Somatic mutation profile of tumor specimen MP2PRT-PAWBWM-TMP1-A (aliquot MP2PRT-PAWBWM-TMP1-A-1-0-D-A80M-36) from MP2PRT case MP2PRT-PAWBWM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,688 days).
Specimen MP2PRT-PAWBWM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05473283-f4ec-4113-819b-9110c3cf3526.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWBWM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWBWM-NB1-A-1-0-D-A80M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d845b57-efa6-4e52-8220-d1f69c8f95cf

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 67/340 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACRBP | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 153/383 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99976056; called by muse, mutect2, varscan2
- FGFR4 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs757092386, COSV52811456; called by muse, mutect2
- TMEM63B | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 40/562 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as rs745439520; called by muse, mutect2
- UNC13C | c.4735C>T p.R1579C | Missense Mutation (SNP) | VAF 112/268 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.828); catalogued as rs763485342, COSV52846015; called by muse, mutect2, varscan2
- ZEB1 | c.2689C>T p.R897W | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1263670005, COSV100314217, COSV58041247; called by muse, mutect2
- LIMCH1 | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MCF2 | c.2733T>A p.N911K | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- NBEA | c.735G>T p.L245F | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- NFIL3 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 205/379 reads (54%) | called by muse, mutect2, varscan2
- PPP4R3B | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYGB | c.1195_1196dup p.H400Gfs*5 | Frame Shift Ins (INS) | VAF 176/351 reads (50%) | called by mutect2, varscan2
- TMPRSS15 | c.1934C>A p.A645E | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.11754A>G p.Q3918= | Silent (SNP) | VAF 133/265 reads (50%) | catalogued as COSV61615390, COSV61633767, COSV61640511; called by muse, mutect2, varscan2
- RAI2 | c.58T>C p.L20= | Silent (SNP) | VAF 17/611 reads (3%) | called by muse, mutect2
